Somatic mutation profile of tumor specimen TCGA-BG-A18A-01A (aliquot TCGA-BG-A18A-01A-21D-A12J-09) from TCGA case TCGA-BG-A18A, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G1; Age at diagnosis: 74.2 years (27,086 days).
Specimen TCGA-BG-A18A-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4e8f855f-fa9d-4542-be74-42d332f8a481.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BG-A18A-10A (Blood Derived Normal), aliquot TCGA-BG-A18A-10A-01D-A12J-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/affb59e3-e5ba-45e1-9089-8e3466fac0c1

The open-access MAF lists 69 somatic variants for this specimen: 46 protein-altering or splice-affecting, 22 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, Silent 22, Nonsense Mutation 4, Frame Shift Del 4, Frame Shift Ins 2, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARID1A | c.3826C>T p.R1276* | Nonsense Mutation (SNP) | VAF 44/72 reads (61%) | hotspot (GDC flag); catalogued as COSV61370466; called by muse, mutect2, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 40/143 reads (28%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CBLL2 | c.268T>A p.Y90N | Missense Mutation (SNP) | VAF 32/77 reads (42%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV60369789; called by muse, mutect2, varscan2
- CELSR2 | c.6941G>A p.R2314Q | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs774014183, COSV54776865; called by muse, mutect2, varscan2
- CENPE | c.3772G>A p.V1258I | Missense Mutation (SNP) | VAF 122/416 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs200458836, COSV54386108; called by muse, mutect2, varscan2
- CHCHD5 | c.40C>T p.R14W | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.333); catalogued as rs1302367664; called by muse, mutect2, varscan2
- CSMD3 | c.4766G>A p.G1589E (on ENST00000297405 / NM_001363185.1; = p.G1485E on NM_052900.3) | Missense Mutation (SNP) | VAF 58/170 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs1379770381, COSV52263571; called by muse, mutect2, varscan2
- CYSLTR1 | c.697G>A p.G233R | Missense Mutation (SNP) | VAF 53/192 reads (28%) | SIFT tolerated (0.36); PolyPhen benign (0.005); catalogued as COSV64819797, COSV64820875; called by muse, mutect2, varscan2
- DHX35 | c.362C>T p.A121V | Missense Mutation (SNP) | VAF 23/108 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52672731; called by muse, mutect2, varscan2
- FAM98B | c.664C>T p.R222* | Nonsense Mutation (SNP) | VAF 79/247 reads (32%) | catalogued as COSV59843131, COSV59843161; called by muse, mutect2, varscan2
- FBXO22 | c.404T>C p.L135P | Missense Mutation (SNP) | VAF 48/178 reads (27%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.936); catalogued as COSV57618332; called by muse, mutect2, varscan2
- FOXA2 | c.697T>A p.W233R (on ENST00000377115 / NM_153675.3; = p.W239R on NM_021784.5) | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65796771; called by muse, mutect2, varscan2
- FXR2 | c.1153C>G p.L385V | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as COSV51469190; called by muse, mutect2
- GIPC1 | c.890C>T p.P297L | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.241); catalogued as rs765648490, COSV52876006, COSV99466499; called by muse, mutect2, varscan2
- HERC1 | c.14456C>T p.P4819L | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs756534965, COSV71248143; called by muse, mutect2, varscan2
- HTR7 | c.1222C>T p.R408W | Missense Mutation (SNP) | VAF 35/123 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV53285483, COSV53286176; called by muse, mutect2, varscan2
- INSL4 | c.349C>T p.R117C | Missense Mutation (SNP) | VAF 51/154 reads (33%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.043); catalogued as rs575960188, COSV53329072, COSV53329665; called by muse, mutect2, varscan2
- KATNAL1 | c.256del p.V86Cfs*35 | Frame Shift Del (DEL) | VAF 73/254 reads (29%) | catalogued as COSV66064152; called by mutect2, pindel, varscan2
- KLHL42 | c.1136T>C p.V379A | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.34); PolyPhen benign (0.014); catalogued as COSV67146088; called by muse, mutect2, varscan2
- LRRC49 | c.1094G>C p.R365T | Missense Mutation (SNP) | VAF 42/160 reads (26%) | SIFT tolerated (0.76); PolyPhen benign (0.03); catalogued as COSV53013535; called by muse, mutect2, varscan2
- LSM12 | c.301C>G p.Q101E | Missense Mutation (SNP) | VAF 29/107 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.222); catalogued as COSV53233058; called by muse, mutect2, varscan2
- MAGEA6 | c.751G>A p.V251M | Missense Mutation (SNP) | VAF 69/246 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.936); catalogued as rs782484544, COSV61449270; called by muse, mutect2, varscan2
- MON2 | c.1604C>A p.S535* | Nonsense Mutation (SNP) | VAF 76/196 reads (39%) | catalogued as COSV54812067; called by muse, mutect2, varscan2
- OR52W1 | c.380G>A p.R127H | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.868); catalogued as rs146972287; called by muse, mutect2, varscan2
- PBK | c.302G>A p.R101H | Missense Mutation (SNP) | VAF 53/180 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs746900679, COSV57272942; called by muse, mutect2, varscan2
- PIK3C2B | c.380A>G p.Y127C | Missense Mutation (SNP) | VAF 67/195 reads (34%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.001); catalogued as rs956886757, COSV65804007; called by muse, mutect2, varscan2
- POLE | c.2926C>A p.R976S | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV57681114, COSV57686493; called by muse, mutect2, varscan2
- POLH | c.1789T>A p.L597M | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.467); catalogued as COSV64780497; called by muse, mutect2, varscan2
- PTEN | c.935del p.D312Afs*5 | Frame Shift Del (DEL) | VAF 45/236 reads (19%) | catalogued as COSV64302377; called by mutect2, pindel, varscan2
- PYROXD1 | c.439G>T p.A147S | Missense Mutation (SNP) | VAF 35/132 reads (27%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.889); catalogued as COSV53711046; called by muse, mutect2, varscan2
- RPF1 | c.67G>A p.E23K | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as rs1442904366, COSV65724610; called by muse, mutect2, varscan2
- RXFP3 | c.896C>T p.A299V | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1348968832, COSV57507159; called by muse, mutect2, varscan2
- SLC43A1 | c.1225C>T p.R409C | Missense Mutation (SNP) | VAF 114/421 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs765376956, COSV53560538; called by muse, mutect2, varscan2
- SMARCA1 | c.1852C>T p.R618C | Missense Mutation (SNP) | VAF 74/277 reads (27%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.88); catalogued as rs773042691, COSV100946713, COSV64412436; called by muse, mutect2, varscan2
- SPTA1 | c.2671C>T p.R891* | Nonsense Mutation (SNP) | VAF 57/186 reads (31%) | catalogued as rs755630903, CM148356, COSV63749670; called by muse, mutect2, varscan2
- SZT2 | c.6550C>T p.R2184C (on ENST00000634258 / NM_001365999.1; = p.R2127C on NM_015284.4) | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65172487; called by muse, mutect2, varscan2
- TASOR2 | c.3619G>A p.D1207N | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT tolerated (0.49); PolyPhen benign (0.062); catalogued as COSV60168767; called by muse, mutect2, varscan2
- TCF21 | c.150G>T p.Q50H | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.018); catalogued as COSV52819002; called by muse, mutect2, varscan2
- TCTN2 | c.329C>T p.T110I | Missense Mutation (SNP) | VAF 78/275 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as COSV57634210; called by muse, mutect2, varscan2
- TRAM2 | c.860A>G p.N287S | Missense Mutation (SNP) | VAF 29/98 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.285); catalogued as rs752268807, COSV51734072; called by muse, mutect2, varscan2
- VPS13B | c.6082T>C p.F2028L | Missense Mutation (SNP) | VAF 36/124 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV62151849; called by muse, mutect2, varscan2
- ZMPSTE24 | c.1234C>A p.R412S | Missense Mutation (SNP) | VAF 38/127 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101031875, COSV65639933; called by muse, mutect2, varscan2
- ATAD2 | c.1499dup p.D500Efs*5 | Frame Shift Ins (INS) | VAF 64/262 reads (24%) | called by mutect2, pindel, varscan2
- CDK19 | c.528del p.F176Lfs*9 | Frame Shift Del (DEL) | VAF 37/146 reads (25%) | called by mutect2, pindel, varscan2
- PTEN | c.473_476del p.V158Gfs*8 | Frame Shift Del (DEL) | VAF 70/176 reads (40%) | called by pindel, varscan2
- SOX17 | c.1219dup p.Y407Lfs*7 | Frame Shift Ins (INS) | VAF 8/27 reads (30%) | called by mutect2, pindel, varscan2
- AP3M1 | c.375C>A p.T125= | Silent (SNP) | VAF 23/452 reads (5%) | catalogued as COSV62332103; called by muse, mutect2
- CRYBG2 | c.4713C>T p.Y1571= | Silent (SNP) | VAF 20/30 reads (67%) | catalogued as rs373509277, COSV57483783; called by muse, mutect2, varscan2
- DDX49 | c.966C>T p.N322= | Silent (SNP) | VAF 12/37 reads (32%) | catalogued as COSV55357996; called by muse, mutect2, varscan2
- ERG | c.861G>T p.V287= (on ENST00000398919 / NM_001243428.1; = p.V263= on NM_004449.4) | Silent (SNP) | VAF 44/188 reads (23%) | catalogued as rs1197674220, COSV55736804; called by muse, mutect2, varscan2
- FLT3 | c.273G>A p.L91= | Silent (SNP) | VAF 40/111 reads (36%) | catalogued as COSV54063249; called by muse, mutect2, varscan2
- GNE | c.2205C>T p.P735= (on ENST00000396594 / NM_001128227.3; = p.P704= on NM_005476.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 36/116 reads (31%) | catalogued as rs779967033, CD156985, COSV64952525; ClinVar: likely benign; called by muse, mutect2, varscan2
- GRIN2B | c.4245G>A p.S1415= | Silent (SNP) | VAF 14/40 reads (35%) | catalogued as rs150956675; ClinVar: likely benign; called by muse, mutect2, varscan2
- H2BC10 | c.57G>A p.V19= | Silent (SNP) | VAF 73/218 reads (33%) | catalogued as rs200674212, COSV100010326, COSV59953473; called by muse, mutect2, varscan2
- HSPG2 | c.10515C>T p.A3505= | Silent (SNP) | VAF 16/32 reads (50%) | catalogued as rs763918034, COSV65933630; called by muse, mutect2, varscan2
- INTS1 | c.2676G>A p.A892= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as rs1287398644, COSV67178878; called by muse, mutect2
- KATNAL1 | c.468T>C p.Y156= | Silent (SNP) | VAF 102/328 reads (31%) | catalogued as rs947661498, COSV66064148; called by muse, mutect2, varscan2
- LSS | c.1173C>T p.F391= | Silent (SNP) | VAF 34/88 reads (39%) | catalogued as rs565649711, COSV62702042; called by muse, mutect2, varscan2
- MORN5 | c.435C>T p.N145= | Silent (SNP) | VAF 33/109 reads (30%) | catalogued as rs536933863, COSV65648421; called by muse, mutect2, varscan2
- MYH7 | c.4602G>A p.E1534= | Silent (SNP) | VAF 10/59 reads (17%) | catalogued as COSV62521939; called by muse, mutect2, varscan2
- NBEA | c.558C>A p.A186= | Silent (SNP) | VAF 43/165 reads (26%) | catalogued as COSV59807895; called by muse, mutect2, varscan2
- NCAM2 | c.1623C>A p.I541= | Silent (SNP) | VAF 41/160 reads (26%) | catalogued as COSV53090002, COSV53092661; called by muse, mutect2, varscan2
- NES | c.4602T>A p.G1534= | Silent (SNP) | VAF 6/37 reads (16%) | catalogued as COSV63962135; called by muse, mutect2, varscan2
- NOVA2 | c.306G>A p.K102= | Silent (SNP) | VAF 96/341 reads (28%) | catalogued as COSV54359029; called by muse, mutect2, varscan2
- PHKG2 | c.888C>T p.G296= | Silent (SNP) | VAF 15/33 reads (45%) | catalogued as COSV60313148; called by muse, mutect2, varscan2
- PTEN | c.480C>G p.T160= | Silent (SNP) | VAF 70/151 reads (46%) | catalogued as COSV64290635, COSV64302373; called by muse, varscan2
- RBP3 | c.3270C>T p.S1090= | Silent (SNP) | VAF 66/179 reads (37%) | called by muse, mutect2, varscan2
- RYR2 | c.1362A>C p.L454= | Silent (SNP) | VAF 46/154 reads (30%) | catalogued as COSV63702804; called by muse, mutect2, varscan2
- TRPV2 | chr17:16439308 G>T | 3'Flank (SNP) | VAF 4/22 reads (18%) | called by muse, mutect2
